EXCEPTIONAL_RESPONDERS case ER-ACGR — Exceptional Responders (EXCEPTIONAL_RESPONDERS-ER)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Adenomas and Adenocarcinomas; Primary site: Bronchus and lung. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/68cf6fcd-e43e-4e39-9f8a-a37c95a5a01a

Demographics
Sex at birth: female; Year of birth: 1959; Vital status: Alive.

Diagnoses (1)
1. Adenocarcinoma, NOS: ICD-O-3 morphology code: 8140/3; Tissue or organ of origin: Lung, NOS; Site of resection or biopsy: Lung, NOS; Classification of tumor: primary; Age at diagnosis: 52.1 years (19,015 days); Year of diagnosis: 2011; AJCC pathologic stage: Stage IV; Prior malignancy: no; Days to last follow up: 1,586 days (4.3 years); Days to best overall response: 75 days; Best overall response: Partial Response.
   Treatment given: Therapeutic agents: Carboplatin; Days to treatment start: 34 days; Days to treatment end: 139 days.
   Treatment given: Therapeutic agents: Pemetrexed; Days to treatment start: 34 days; Days to treatment end: 160 days.

Follow-up (1 entry)
- Days to follow up: 1,586 days (4.3 years); Disease response: Stable Disease; Progression or recurrence: No; Days progression-free: 1,586 days (4.3 years).

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample ER-ACGR-NB1-A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.
- Sample ER-ACGR-TTM1-A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Preservation method: FFPE.
  Slide ER-ACGR-TTM1-A-1-0-S1: Section location: Top; Percent tumor cells: 70; Percent tumor nuclei: 70; Percent normal cells: 0; Percent necrosis: 20; Percent stromal cells: 10; Percent lymphocyte infiltration: 0; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample ER-ACGR-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: FFPE.
  Slide ER-ACGR-TTP1-A-1-0-S1: Section location: Top; Percent tumor cells: 10; Percent tumor nuclei: 15; Percent normal cells: 0; Percent necrosis: 50; Percent stromal cells: 40; Percent lymphocyte infiltration: 80; Percent monocyte infiltration: 20; Percent neutrophil infiltration: 0.
